Somatic mutation profile of tumor specimen TCGA-28-2501-01A (aliquot TCGA-28-2501-01A-01D-1696-08) from TCGA case TCGA-28-2501, project TCGA-GBM (Glioblastoma Multiforme).
Specimen TCGA-28-2501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a640c53-08d1-4a5d-9ff2-7b60b9d4213a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2501-10A (Blood Derived Normal), aliquot TCGA-28-2501-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82413c0b-31b3-4a81-b470-ba7c7b1d5c53

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Intron 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL8 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1165059846, COSV100958717; called by muse, mutect2, varscan2
- BBS9 | c.1561C>T p.R521* (on ENST00000242067 / NM_001348036.1; = p.R481* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs748601675, COSV54157359; called by muse, mutect2, varscan2
- BRD3 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs988329845; called by muse, mutect2, varscan2
- CNTNAP2 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs367642984; called by muse, mutect2, varscan2
- DGKG | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760665571, COSV53969104; called by muse, mutect2, varscan2
- DNAH2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145686578; called by muse, mutect2, varscan2
- DOCK10 | c.3899A>G p.N1300S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1469480949; called by muse, mutect2, varscan2
- EVPL | c.4019C>T p.A1340V | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs375290979; called by muse, mutect2, varscan2
- FMR1NB | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs376382924, COSV100789545; called by muse, mutect2, varscan2
- HMCN1 | c.3044C>G p.S1015C | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV54943715; called by muse, mutect2, varscan2
- ITGB3 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs774343946, COSV71383917; called by muse, mutect2, varscan2
- KCNK1 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs767247742, COSV64035053; called by muse, mutect2, varscan2
- MC3R | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1286756644, COSV54762849; called by muse, mutect2, varscan2
- MDC1 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs763377150, COSV64524815; called by muse, mutect2, varscan2
- MUC16 | c.17833G>A p.A5945T | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199743326, COSV67499634; called by muse, mutect2, varscan2
- MYO3A | c.4411C>T p.R1471* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs1260537975; called by muse, mutect2, varscan2
- NLRP3 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs766157536; called by muse, mutect2, varscan2
- OR5AR1 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57254110; called by muse, mutect2, varscan2
- PTPRR | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150540173; called by mutect2, varscan2
- SLC5A7 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs935822553, COSV50901443, COSV50909428; called by muse, mutect2
- SLIT3 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766150043, COSV60595120; called by muse, mutect2, varscan2
- SPAG9 | c.3058G>A p.G1020S (on ENST00000262013 / NM_001130528.3; = p.G1006S on NM_003971.6) | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56230568; called by muse, mutect2, varscan2
- TTN | c.33250G>A p.E11084K (on ENST00000591111; = p.E10157K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | PolyPhen benign (0.361); catalogued as rs765827814, COSV59915823; ClinVar: benign / uncertain significance; called by muse, mutect2
- TTN | c.6953G>A p.R2318H (on ENST00000591111; = p.R2272H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | PolyPhen probably damaging (0.998); catalogued as rs761566436, COSV60182770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBA7 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs201219751, COSV61092439; called by muse, mutect2, varscan2
- CMYA5 | c.1958T>C p.L653P | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CPT2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND1C | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DNAH9 | c.6473C>T p.S2158L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- HEATR1 | c.4556C>A p.S1519Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- IRX1 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2
- MYO18B | c.3003C>A p.D1001E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- RBBP5 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCNN1D | c.862A>G p.T288A (on ENST00000338555; = p.T452A on NM_001130413.4) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ABLIM3 | c.930G>T p.A310= | Silent (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
- AMBN | c.1251G>A p.T417= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs570826995; called by muse, mutect2
- ANKS6 | c.1851C>T p.S617= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- BDH1 | c.885G>A p.T295= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as rs774640647; called by muse, mutect2, varscan2
- CD300LB | c.258G>A p.T86= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as rs763129538, COSV58725218; called by muse, mutect2, varscan2
- DMTF1 | c.1077A>G p.E359= | Silent (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- ENGASE | c.267G>T p.S89= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs375589820; called by muse, mutect2, varscan2
- EPB42 | c.1200G>A p.E400= (on ENST00000441366 / NM_001114134.2; = p.E430= on NM_000119.3) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1278632382; called by muse, mutect2
- EPHB1 | c.1155C>A p.G385= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- PKLR | c.1089G>A p.A363= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs773644908; called by muse, mutect2, varscan2
- SCMH1 | c.1116C>T p.H372= (on ENST00000326197 / NM_001031694.2; = p.H325= on NM_012236.4) | Silent (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- TSPEAR | c.828G>A p.P276= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs371022077; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129524_276-129523del | Intron (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- PRR5-ARHGAP8 | c.929+6233C>T | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as rs1569155715; called by muse, mutect2, varscan2
